Somatic mutation profile of tumor specimen ALCH-B41A-TTP1-A (aliquot ALCH-B41A-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B41A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.6 years (26,894 days).
Specimen ALCH-B41A-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0eea8b72-4c61-43b5-8ecc-1178113a729b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B41A-NB1-A (Blood Derived Normal), aliquot ALCH-B41A-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ade22f7d-e050-455a-a188-f8dbffe025b0

The open-access MAF lists 101 somatic variants for this specimen: 64 protein-altering or splice-affecting, 25 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 25, Intron 7, Nonsense Mutation 4, 5'Flank 3, 5'UTR 2, Frame Shift Del 2, In Frame Del 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 423/849 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 21/64 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519930, COSV55874291, COSV55888676, COSV55926774; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.13988C>T p.S4663L | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201250142; called by muse, mutect2, varscan2
- ABCC9 | c.2581G>C p.D861H | Missense Mutation (SNP) | VAF 44/385 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV53977460; called by muse, mutect2, varscan2
- ADGRE2 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.018); catalogued as rs142367407; called by muse, mutect2
- CACNA1I | c.3818T>G p.V1273G | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60805906; called by muse, mutect2, varscan2
- CALR3 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 87/924 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54168287, COSV54168583; called by muse, mutect2
- CCR2 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.611); catalogued as rs539087679, COSV52748389; called by muse, mutect2, varscan2
- CFAP94 | c.82G>C p.E28Q (on ENST00000320267 / NM_001352064.2; = p.E34Q on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/412 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as COSV100209558, COSV57232447; called by muse, mutect2
- DCHS1 | c.1450G>C p.E484Q | Missense Mutation (SNP) | VAF 14/494 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV55033657; called by muse, mutect2
- DISC1 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs142645368; called by muse, mutect2, varscan2
- DNAH8 | c.8698-1G>C p.X2900_splice | Splice Site (SNP) | VAF 9/74 reads (12%) | catalogued as COSV59445188; called by muse, mutect2
- FPR1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.019); catalogued as rs547228145, COSV59053059; called by muse, mutect2, varscan2
- GRIA2 | c.1252G>T p.V418F | Missense Mutation (SNP) | VAF 26/303 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as rs774950399; called by muse, mutect2
- ICE2 | c.1374G>C p.Q458H | Missense Mutation (SNP) | VAF 41/351 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.275); catalogued as rs769641639, COSV55029669; called by muse, mutect2, varscan2
- KCNH5 | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.608); catalogued as rs533454331, COSV59757653, COSV59765420; called by mutect2, varscan2
- LINGO1 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs776160711, COSV62438353; called by muse, mutect2
- NAV1 | c.2812C>T p.R938W | Missense Mutation (SNP) | VAF 24/269 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.949); catalogued as rs370373937; called by muse, mutect2
- NRBP1 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51996431; called by muse, mutect2, varscan2
- POLR2C | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 26/462 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV54673873; called by muse, mutect2
- PROCA1 | c.319G>A p.D107N (on ENST00000439862 / NM_001366301.1; = p.D79N on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.149); catalogued as COSV99973125; called by muse, mutect2, varscan2
- PSD3 | c.2300G>A p.R767H (on ENST00000440756; = p.R766H on NM_015310.4) | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs376989905; called by muse, mutect2, varscan2
- RB1 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1060503084, COSV57301804, COSV57330725; ClinVar: uncertain significance; called by muse, mutect2
- SDC2 | c.344C>G p.S115C | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as rs777002637, COSV100143652, COSV100143813; called by muse, mutect2
- SHANK2 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 100/501 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs782738905, COSV53602300; called by muse, mutect2, varscan2
- SLC17A2 | c.1112C>A p.S371Y | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.596); catalogued as COSV99613903; called by muse, mutect2, varscan2
- SLC39A13 | c.501G>C p.K167N | Missense Mutation (SNP) | VAF 60/477 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV61521136; called by muse, mutect2, varscan2
- SLC7A14 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 52/590 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99200701; called by muse, mutect2
- TJP2 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 13/311 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs1199038888; called by muse, mutect2
- TM4SF5 | c.393C>T p.T131= | Splice Region (SNP) | VAF 12/104 reads (12%) | catalogued as rs748076059; called by muse, mutect2
- TMC3 | c.3285G>C p.L1095F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV63923102; called by muse, mutect2, varscan2
- TMTC2 | c.2077A>T p.K693* | Nonsense Mutation (SNP) | VAF 13/151 reads (9%) | catalogued as COSV58279170; called by muse, mutect2
- VSX2 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs775981376, COSV56216669; called by muse, mutect2, varscan2
- ZNF799 | c.1763A>G p.Y588C | Missense Mutation (SNP) | VAF 30/357 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs555977389; called by muse, varscan2
- AIFM3 | c.1389T>A p.F463L | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- ARHGAP26 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ARHGEF12 | c.4181C>T p.S1394L | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated, low confidence (0.64); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CDKN1B | c.10del p.V4Cfs*38 | Frame Shift Del (DEL) | VAF 100/479 reads (21%) | called by mutect2, pindel, varscan2
- COLGALT2 | c.509A>G p.N170S | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CRY1 | c.1241G>T p.C414F | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2
- DGKG | c.184T>A p.Y62N | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DOCK8 | c.4843del p.E1615Nfs*28 | Frame Shift Del (DEL) | VAF 117/324 reads (36%) | called by mutect2, pindel, varscan2
- FCAMR | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- GK3P | c.420G>C p.K140N | Missense Mutation (SNP) | VAF 46/730 reads (6%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.694); called by muse, mutect2
- KCNK1 | c.802T>G p.C268G | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- KIZ | c.1121C>T p.T374I | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- KMT2C | c.3713A>G p.E1238G | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2
- LMBRD1 | c.1466A>T p.D489V (on ENST00000649011; = p.D467V on NM_018368.4) | Missense Mutation (SNP) | VAF 46/428 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.073); called by muse, mutect2
- MAN1C1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K6 | c.582_584del p.L195del | In Frame Del (DEL) | VAF 49/314 reads (16%) | called by mutect2, pindel, varscan2
- MKI67 | c.3301G>C p.D1101H | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MYO3A | c.2605C>T p.Q869* | Nonsense Mutation (SNP) | VAF 51/458 reads (11%) | called by muse, mutect2, varscan2
- NR3C2 | c.2192C>T p.S731L | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2
- NRK | c.1567C>G p.Q523E | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NT5C3A | c.756G>T p.L252F (on ENST00000610140 / NM_001374335.1; = p.L218F on NM_016489.13) | Missense Mutation (SNP) | VAF 101/326 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PLD1 | c.63G>T p.M21I | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- PRKCA | c.1924C>T p.Q642* | Nonsense Mutation (SNP) | VAF 14/234 reads (6%) | called by muse, mutect2
- SNX13 | c.1198C>G p.L400V | Missense Mutation (SNP) | VAF 63/460 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- SPART | c.164G>A p.R55K | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.054); called by muse, mutect2
- STAB2 | c.5019C>A p.N1673K | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2
- TASOR | c.3066G>C p.E1022D (on ENST00000355628 / NM_001365636.2; = p.E646D on NM_015224.3) | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.38); called by muse, mutect2
- TTC33 | c.599C>G p.S200* | Nonsense Mutation (SNP) | VAF 26/279 reads (9%) | called by muse, mutect2, varscan2
- YAP1 | c.1511T>C p.L504S (on ENST00000282441 / NM_001130145.3; = p.L450S on NM_006106.5) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- ZFPM1 | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 23/259 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.262); called by muse, mutect2
- ACVR1 | c.510C>T p.L170= | Silent (SNP) | VAF 44/282 reads (16%) | called by muse, mutect2, varscan2
- ALMS1 | c.8031C>T p.D2677= | Silent (SNP) | VAF 28/275 reads (10%) | called by muse, mutect2, varscan2
- ARMCX4 | c.963G>A p.R321= (on ENST00000433011; = p.R217= on NM_001256155.2) | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs201467260; called by muse, mutect2, varscan2
- CACNB2 | c.834A>G p.V278= (on ENST00000324631 / NM_201596.3; = p.V223= on NM_000724.4) | Silent (SNP) | VAF 38/514 reads (7%) | called by muse, mutect2
- CNGB1 | c.3234G>A p.K1078= | Silent (SNP) | VAF 36/388 reads (9%) | catalogued as COSV51898127; called by muse, mutect2
- FANCE | c.1023C>T p.L341= | Silent (SNP) | VAF 24/560 reads (4%) | called by muse, mutect2
- GCKR | c.450G>A p.E150= | Silent (SNP) | VAF 51/318 reads (16%) | called by muse, mutect2, varscan2
- GDF7 | c.564C>T p.A188= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as rs963935983; called by muse, mutect2
- LRRK2 | c.5983C>T p.L1995= | Silent (SNP) | VAF 32/311 reads (10%) | called by muse, mutect2, varscan2
- MGAT3 | c.1473C>T p.Y491= | Silent (SNP) | VAF 95/323 reads (29%) | catalogued as rs749847440; called by muse, mutect2, varscan2
- MOV10L1 | c.1020G>A p.K340= | Silent (SNP) | VAF 59/526 reads (11%) | called by muse, mutect2, varscan2
- MST1R | c.442C>T p.L148= | Silent (SNP) | VAF 14/212 reads (7%) | called by muse, mutect2
- MUC16 | c.23256G>A p.E7752= | Silent (SNP) | VAF 37/315 reads (12%) | called by muse, mutect2, varscan2
- MXRA5 | c.1782G>A p.S594= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs756203907, COSV54224498; called by muse, mutect2
- PCDH11Y | c.3033C>T p.S1011= (on ENST00000400457 / NM_032973.2; = p.S1000= on NM_032971.3) | Silent (SNP) | VAF 79/368 reads (21%) | called by muse, mutect2, varscan2
- PDE1B | c.1473G>A p.E491= | Silent (SNP) | VAF 24/303 reads (8%) | catalogued as rs965609591; called by muse, mutect2
- PGR | c.510C>T p.C170= | Silent (SNP) | VAF 39/195 reads (20%) | catalogued as COSV54799808; called by muse, mutect2, varscan2
- PKDCC | c.99G>T p.P33= | Silent (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- RTN1 | c.1374C>T p.R458= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV50725250; called by muse, mutect2, varscan2
- SCNN1G | c.483G>A p.L161= | Silent (SNP) | VAF 50/632 reads (8%) | called by muse, mutect2
- SH3BGRL | c.198A>G p.P66= | Silent (SNP) | VAF 8/189 reads (4%) | called by muse, mutect2
- SUPT20HL1 | c.609G>A p.A203= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as rs1321652529; called by muse, mutect2, varscan2
- TMTC2 | c.2079G>A p.K693= | Silent (SNP) | VAF 15/161 reads (9%) | catalogued as rs775326406; called by muse, mutect2
- TNFRSF1B | c.12C>T p.V4= | Silent (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2
- ZNF559-ZNF177 | c.759G>A p.V253= | Silent (SNP) | VAF 51/195 reads (26%) | called by muse, mutect2, varscan2
- AC026271.3 | chr17:18701392 G>A | 5'Flank (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- CFAP91 | c.124+21T>G | Intron (SNP) | VAF 12/131 reads (9%) | called by muse, mutect2
- CHRNB1 | c.59-35G>A | Intron (SNP) | VAF 9/254 reads (4%) | called by muse, mutect2
- GLDC | c.2838+48A>G | Intron (SNP) | VAF 42/128 reads (33%) | catalogued as rs749610517; called by mutect2, varscan2
- KCNH7 | c.-10C>T | 5'UTR (SNP) | VAF 6/120 reads (5%) | catalogued as rs1405435369, COSV100037194; called by muse, mutect2
- LDLRAP1 | c.617-13G>A | Intron (SNP) | VAF 64/618 reads (10%) | catalogued as rs549476432; called by muse, mutect2, varscan2
- MUC19 | chr12:40561371 A>C | 5'Flank (SNP) | VAF 31/248 reads (13%) | called by muse, mutect2, varscan2
- PPP3CA | chr4:101348446 G>A | 5'Flank (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- RHBG | c.188-2638C>T | Intron (SNP) | VAF 4/70 reads (6%) | catalogued as rs1371960543; called by muse, mutect2
- SERPINA3 | c.1068+40G>A | Intron (SNP) | VAF 38/309 reads (12%) | catalogued as rs529091841; called by muse, mutect2, varscan2
- SSR4 | c.262-84C>T | Intron (SNP) | VAF 9/73 reads (12%) | catalogued as rs782323326; called by muse, mutect2, varscan2
- VPS29 | c.-48G>A | 5'UTR (SNP) | VAF 28/346 reads (8%) | catalogued as rs779145268, COSV100799466; called by muse, mutect2
